Somatic mutation profile of tumor specimen PCProject_0048_T1_WES (aliquot PCProject_0048_T1_WES_1) from CMI case PCProject_0048, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.8 years (21,129 days).
Specimen PCProject_0048_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b6dda6-063d-4878-9078-ba5d205d6f93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0048_SALIVA (Saliva), aliquot PCProject_0048_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c82de32a-d5c8-47b5-bc82-79e7c0788c34

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL2 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as rs1554857256, COSV66079665; called by muse, mutect2
- CYP2C9 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1213307859; called by muse, mutect2, varscan2
- MUC4 | c.6128C>G p.T2043R | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.517); catalogued as rs1363155476; called by muse, mutect2
- SPHK2 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1043398066; called by mutect2, varscan2
- ATAD2B | c.407A>C p.H136P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ATP5MF | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAP4 | c.60_61del p.E20Dfs*15 | Frame Shift Del (DEL) | VAF 17/161 reads (11%) | called by pindel, varscan2
- NDST2 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- RUSC1 | c.2125del p.T709Lfs*25 (on ENST00000368352 / NM_001105203.2; = p.T240Lfs*25 on NM_014328.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- SIDT1 | c.2177C>G p.A726G | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- TMPRSS15 | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF398 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCE3D | c.150C>T p.G50= | Silent (SNP) | VAF 25/238 reads (11%) | catalogued as rs139649941, COSV64230545; called by muse, mutect2, varscan2
- PCDH11Y | c.3066C>T p.S1022= (on ENST00000400457 / NM_032973.2; = p.S1011= on NM_032971.3) | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TNR | c.2655C>T p.S885= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 6/106 reads (6%) | catalogued as rs910081914; called by muse, mutect2
